Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3861, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3861-01A (Primary Tumor).

Diagnosis:

Block A shows an invasive adenocarcinoma of the colon (cecal carcinoma G3), with a marked tendency toward infiltration into the adjoining fatty connective tissue and vascular infiltration (G3, pT3, L1, V1), while Block B shows an additional polyp, here of tubular adenoma type with focal severe dysplasia and transition to a circumscribed adenocarcinoma with infiltration of the submucosa (here G2, pT1), with regard to the resection margins these are free resection margins, orally of the ileum type and distally of the colon type, as well as - with regard to the circumferential margin - free fatty connective tissue and - with regard to the lymph nodes - free lymph nodes (0 to 17).

Tumor classification:

ICDO-DA M 8140/3

G3 – pT3 L1, V1, (1st tumor)

G2 – pT1 L0, V0, (polypoid lesion)

Free lymph nodes (0 of 17), free resection margins, locally R0

Source: NCI Genomic Data Commons file 3b4d6170-a801-418a-9f86-cac422025793 (TCGA-AA-3861.DB8A3784-502F-4F08-B31B-FDF25038A65D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).